Gene-level copy-number profile of tumor specimen TCGA-21-A5DI-01A from TCGA case TCGA-21-A5DI, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 77.7 years (28,374 days).
Specimen TCGA-21-A5DI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.9c53eb8f-beae-496c-afa8-1858d45b60af.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-21-A5DI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9c154ba3-2ca4-4577-b189-e380cc6cba26

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 18,075; copy number 2: 33,159; copy number 3: 4,840; copy number 4: 2,575; copy number 5: 654; copy number 6: 267; copy number 7: 143; copy number 8: 50; copy number 15: 19; copy number 32: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-21-A5DI-01): tumor purity 0.3, ploidy 3.15, whole-genome doublings 1 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,168 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:6,839,460–7,219,291, 1 gene, copy number 6 (within-gene range 4–6): LINC02196.
- chr5:7,047,227–23,689,386, 245 genes, copy number 6–7 (broad region; genes not listed).
- chr5:26,669,346–28,809,291, 15 genes, copy number 6: AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL, AC113355.1, AC093300.1, LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2.
- chr5:28,897,785–28,927,459, 4 genes, copy number 6: AC010385.2, LSP1P3, AC010385.1, AC010385.3.
- chr7:54,759,348–56,381,312, 54 genes, copy number 15–32: SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2, IFITM3P4, AC006970.1, AC006970.2, CCNJP1, AC073136.1, AC073136.2, AC093392.1, RNU6-1335P, SEPTIN14P24, CICP8, AC093392.2.
- chr11:19,029,697–21,575,686, 34 genes, copy number 5: MRGPRX9P, MRGPRX2, ZDHHC13, CSRP3, CSRP3-AS1, E2F8, PCNAP4, AC009652.1, NAV2, NAV2-IT1, RNA5SP335, NAV2-AS5, NAV2-AS4, MIR4486, AC023950.1, AC009549.1, MIR4694, NAV2-AS3, NAV2-AS2, NAV2-AS1, AC068860.1, DBX1, HTATIP2, PRMT3, HMGB1P40, AC090707.2, SLC6A5, NELL1, AC090707.1, RNA5SP336, AC090857.1, AC090857.2, AC099730.1, RNA5SP337.
- chr11:23,370,116–26,047,598, 20 genes, copy number 6: AC100767.2, WIZP1, MIR8054, AC100767.1, THAP12P4, AC068472.1, LINC02726, AC100768.1, RNU6-783P, AC099842.1, LINC02686, Y_RNA, LUZP2, AC115990.1, AC087373.1, RPL36AP40, AC100770.1, LINC02699, AC013799.1, AC024341.1.
- chr11:26,244,640–26,331,289, 2 genes, copy number 6: AC021698.1, ANO3-AS1.
- chr12:66,767–10,613,609, 395 genes, copy number 5 (broad region; genes not listed).
- chr12:16,347,142–29,340,980, 199 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:47,593,208–48,040,761, 25 genes, copy number 5: AC004486.1, RPAP3, AC004241.3, AC004241.1, ENDOU, AC004241.5, AC004241.2, RAPGEF3, SLC48A1, AC004241.4, HDAC7, AC004466.1, AC004466.3, AC004466.2, LINC02354, VDR, AC121338.1, AC121338.2, AC004801.7, TMEM106C, COL2A1, AC004801.5, AC004801.4, AC004801.3, AC004801.6.
- chr12:48,054,813–48,055,591, 1 gene, copy number 5: AC004801.2.
- chr12:63,844,700–67,352,039, 84 genes, copy number 6–8 (within-gene range 2–8) (broad region; genes not listed).
- chr12:68,911,921–70,920,738, 38 genes, copy number 6 (within-gene range 4–6): RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1.
- chr17:50,475,819–51,297,936, 38 genes, copy number 8 (within-gene range 1–8): AC021491.4, RSAD1, AC021491.1, MYCBPAP, AC021491.2, EPN3, SPATA20, CACNA1G-AS1, CACNA1G, AC021491.3, AC004590.1, ABCC3, ANKRD40, AC005921.2, Y_RNA, LUC7L3, AC005921.3, ANKRD40CL, MIR8059, AC005921.4, AC005921.1, WFIKKN2, AC091062.1, RPL5P33, TOB1, TOB1-AS1, AC005920.4, AC005920.1, AC005920.3, SPAG9, AC005920.2, NME1, NME1-NME2, NME2, MBTD1, AC005839.1, AC006141.1, UTP18.
- chr21:20,998,409–22,420,819, 13 genes, copy number 6 (within-gene range 4–6): NCAM2, AP001136.1, AP001117.1, AF241725.1, LINC00317, LINC01425, AP000472.1, LINC01687, LINC00308, AP000705.2, AP000705.1, RNU4-45P, AP000561.1.

Autosomal genes at a single copy (total copy number 1): 18,041. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
